Somatic mutation profile of tumor specimen C3N-02579-02 (aliquot CPT0207780010) from CPTAC case C3N-02579, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 51.8 years (18,922 days).
Specimen C3N-02579-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f868f88-cf36-4c2d-bf49-09fd5665eb83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02579-71 (Blood Derived Normal), aliquot CPT0207830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d9f88d9-f057-4bc4-9a35-93bd5c98792f

The open-access MAF lists 45 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 12, Intron 5, 3'UTR 2, In Frame Del 2, Frame Shift Del 1, Nonsense Mutation 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 81/322 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 178/660 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs185459023, COSV100947479; called by muse, mutect2, varscan2
- AUTS2 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 69/461 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750187638; called by muse, mutect2, varscan2
- CCT6B | c.1435G>A p.V479I | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs779683070, COSV58490240; called by muse, mutect2, varscan2
- CDKN2A | c.47_50del p.L16Pfs*9 | Frame Shift Del (DEL) | VAF 74/394 reads (19%) | catalogued as rs587782206; called by pindel, varscan2
- CNTN6 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 69/378 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs774492055, COSV63172416; called by muse, mutect2, varscan2
- ERCC2 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 86/652 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs199738290, COSV67264471; ClinVar: not provided; called by muse, mutect2, varscan2
- MAP3K21 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 192/585 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs149651212; called by muse, mutect2, varscan2
- MYH7 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 30/978 reads (3%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV62521052; called by muse, mutect2
- PIWIL3 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775556342, COSV59993917; called by muse, mutect2, varscan2
- PRR35 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.305); catalogued as rs747782968; called by muse, mutect2, varscan2
- UBQLNL | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs748666024, COSV100975216; called by muse, mutect2, varscan2
- WASHC5 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 90/517 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs374338104; called by muse, mutect2, varscan2
- BAAT | c.604A>T p.K202* | Nonsense Mutation (SNP) | VAF 136/607 reads (22%) | called by muse, mutect2, varscan2
- CCDC188 | c.1174C>A p.L392M | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CNTNAP1 | c.3721_3723del p.V1241del | In Frame Del (DEL) | VAF 100/682 reads (15%) | called by mutect2, pindel, varscan2
- ENOX2 | c.1070A>G p.K357R (on ENST00000338144 / NM_001382520.1; = p.K328R on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ICAM3 | c.1581_1586del p.P529_L530del | In Frame Del (DEL) | VAF 39/304 reads (13%) | called by mutect2, pindel, varscan2
- IGHV3-49 | c.250T>C p.S84P | Missense Mutation (SNP) | VAF 22/583 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.438); called by muse, mutect2
- NKPD1 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 111/556 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- TEC | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TGM2 | c.1676A>T p.N559I | Missense Mutation (SNP) | VAF 197/799 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VRK3 | c.1373A>C p.Q458P | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- INTS8 | c.2433T>C p.F811= | Silent (SNP) | VAF 55/274 reads (20%) | called by muse, mutect2, varscan2
- LMTK3 | c.264G>A p.A88= | Silent (SNP) | VAF 42/275 reads (15%) | catalogued as rs1349901718, COSV54311884; called by muse, mutect2, varscan2
- MUC16 | c.10548A>G p.L3516= | Silent (SNP) | VAF 20/411 reads (5%) | catalogued as rs1430745369; called by muse, mutect2
- NCOA7 | c.840C>T p.L280= | Silent (SNP) | VAF 45/163 reads (28%) | called by muse, mutect2, varscan2
- PCDH10 | c.1149T>A p.T383= | Silent (SNP) | VAF 52/356 reads (15%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1095C>A p.T365= | Silent (SNP) | VAF 82/311 reads (26%) | called by muse, mutect2, varscan2
- PRKD2 | c.586C>T p.L196= | Silent (SNP) | VAF 47/317 reads (15%) | catalogued as rs747367197; called by muse, mutect2, varscan2
- SIGIRR | c.675C>A p.I225= | Silent (SNP) | VAF 78/350 reads (22%) | catalogued as COSV100230238; called by muse, mutect2, varscan2
- ST6GAL2 | c.801C>T p.T267= | Silent (SNP) | VAF 47/201 reads (23%) | catalogued as rs559643382; called by muse, mutect2, varscan2
- TMPRSS11A | c.432T>C p.N144= | Silent (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- TSPAN31 | c.75G>A p.L25= | Silent (SNP) | VAF 40/249 reads (16%) | called by muse, mutect2, varscan2
- ZNRF3 | c.393G>A p.L131= (on ENST00000544604 / NM_001206998.2; = p.L31= on NM_032173.3) | Silent (SNP) | VAF 41/228 reads (18%) | catalogued as rs746248781; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502756 C>T | 5'Flank (SNP) | VAF 11/177 reads (6%) | catalogued as rs1283973417; called by muse, mutect2
- ARMCX4 | c.1038+2354C>T | Intron (SNP) | VAF 12/346 reads (3%) | called by muse, mutect2
- C10orf143 | c.69+2832C>T | Intron (SNP) | VAF 98/484 reads (20%) | catalogued as rs1470614410; called by muse, mutect2, varscan2
- EEF2 | c.613-140T>A | Intron (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2
- FCN1 | c.*437C>A | 3'UTR (SNP) | VAF 14/386 reads (4%) | called by muse, mutect2
- KCNA1 | c.*57dup | 3'UTR (INS) | VAF 36/213 reads (17%) | catalogued as rs767865722; called by mutect2, pindel, varscan2
- MDGA2 | c.2752+1574del | Intron (DEL) | VAF 27/169 reads (16%) | called by mutect2, pindel, varscan2
- PKD1L2 | n.2930C>A | RNA (SNP) | VAF 105/510 reads (21%) | called by muse, mutect2, varscan2
- PPP3CC | c.943+894A>T | Intron (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
